Gene-level copy-number profile of tumor specimen TARGET-40-PAPIJR-01A from TARGET case TARGET-40-PAPIJR, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.6 years (4,597 days).
Specimen TARGET-40-PAPIJR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.4897fbf0-729d-5923-b824-917722e4d6d8.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAPIJR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 403 have no estimate.
https://portal.gdc.cancer.gov/files/12bf7fec-90cc-41fe-992d-95982c6f9267

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 767; copy number 1: 10,746; copy number 2: 23,733; copy number 3: 14,545; copy number 4: 5,799; copy number 5: 2,671; copy number 6: 644; copy number 7: 301; copy number 8: 214; copy number 9: 115; copy number 10: 53; copy number 11: 268; copy number 12: 2; copy number 13: 21; copy number 14: 202; copy number 15: 76; copy number 16: 3; copy number 17: 14; copy number 18: 19; copy number 20: 6; copy number 22: 5; copy number 24: 9; copy number 25: 1; copy number 28: 6.

Homozygous deletions (total copy number 0; autosomes only): 247 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,582,552–117,027,039, 9 genes: RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr3:175,059,361–175,115,242, 2 genes: EEF1B2P8, NAALADL2-AS3.
- chr5:165,349,030–165,905,608, 4 genes (within-gene range 0–2): AC008415.1, RN7SKP60, AC008562.1, AC008489.1.
- chr7:147,146,342–147,167,572, 2 genes: DUTP3, RANP2.
- chr8:5,659,679–10,428,891, 172 genes (within-gene range 0–1) (broad region; genes not listed).
- chr8:49,909,789–52,943,734, 26 genes (within-gene range 0–2): SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1.
- chr9:102,055,252–102,055,741, 1 gene: ARL2BPP7.
- chr10:54,486,230–54,656,051, 3 genes (within-gene range 0–7): AL353784.1, NEFMP1, MIR548F1.
- chr11:80,321,620–80,762,826, 4 genes: AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720.
- chr11:81,175,201–81,556,425, 3 genes: AP003464.1, MTND4LP18, MTND6P25.
- chr11:84,545,131–84,640,565, 2 genes: HNRNPA1P72, AP000852.1.
- chr15:24,341,729–24,343,464, 1 gene: AC087463.3.
- chr17:13,494,032–14,349,404, 14 genes (within-gene range 0–4): HS3ST3A1, MIR548H3, COX10-AS1, AC005304.2, AC005304.1, AC005304.3, CDRT15P1, COX10, SNORA74, CDRT15, AC005224.1, HS3ST3B1, AC005224.3, AC005224.2.
- chr19:52,588,505–52,597,345, 1 gene: ZNF137P.
- chr19:52,597,699–52,598,887, 1 gene: AC022150.2.
- chr22:44,702,233–44,862,788, 2 genes (within-gene range 0–2): PRR5-ARHGAP8, ARHGAP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,571 genes in 80 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:80,451,083–84,786,714, 51 genes, copy number 5: HNRNPA1P64, AL596276.1, AL596276.2, AL136234.1, LINC01781, MTND2P30, RPL7P10, AL357632.1, AC093154.1, RN7SKP247, ADGRL2, HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8, AC117944.1, AL138799.2, ST13P20, AL157944.1, LINC01362, LINC01361, AC116099.1, LINC01712, LINC01725, AL035706.1, TTLL7, TTLL7-IT1, AC104454.1, AC104454.2, AL359504.1, PRKACB, TXN2P1, NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX, DNASE2B, AL844170.1, RPF1, GNG5, AL359762.3, SPATA1, CTBS, AL359762.1, AL359762.2, LINC01555, AC114482.1, SSX2IP, AC104169.1.
- chr1:168,695,874–169,854,080, 24 genes, copy number 5 (within-gene range 3–5): AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1, CCDC181, SLC19A2, AL021068.1, Z99572.1, F5, SELP, C1orf112, SELL, SELE, AL021940.1.
- chr2:39,664,982–49,888,986, 168 genes, copy number 5 (broad region; genes not listed).
- chr3:11,745–4,467,273, 37 genes, copy number 5 (within-gene range 4–5): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1, DNAJC19P4, CNTN4-AS1, IL5RA, AC024060.1, TRNT1, CRBN, AC024060.2, AC034195.1, SUMF1, LRRN1, AC023480.1, PNPT1P1.
- chr3:23,194,929–36,764,349, 154 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr3:94,506,766–97,752,460, 18 genes, copy number 6 (within-gene range 4–6): ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6.
- chr3:98,463,201–100,577,444, 39 genes, copy number 5: OR5K1, OR5K2, CLDND1, AC021660.3, AC021660.2, RPL38P4, GPR15, AC021660.4, CPOX, AC021660.1, WWP1P1, ST3GAL6-AS1, ST3GAL6, PDLIM1P4, DCBLD2, RNU6-26P, AC091212.1, RNU6-1263P, LINC00973, U7, ACTG1P13, AC107297.1, AC078828.1, AC107029.1, AC107029.2, COL8A1, AC069222.1, CMSS1, FILIP1L, MIR3921, AC129803.1, TMEM30CP, DUSP12P1, VTI1BP1, TBC1D23, NIT2, TOMM70, LNP1, TMEM45A.
- chr3:164,714,095–169,038,416, 47 genes, copy number 5: LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr6:46,852,522–48,068,689, 18 genes, copy number 5 (within-gene range 2–5): ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4.
- chr6:49,344,800–50,857,662, 27 genes, copy number 6: RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5.
- chr7:9,614,978–32,428,131, 355 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:40,135,005–45,186,302, 93 genes, copy number 5 (within-gene range 4–9) (broad region; genes not listed).
- chr8:62,855,068–63,693,249, 17 genes, copy number 5: XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2.
- chr8:71,155,454–73,441,526, 36 genes, copy number 5: AC022858.1, EYA1, TRAPPC2P2, AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1.
- chr8:85,495,693–90,095,475, 62 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr8:96,370,800–100,663,415, 80 genes, copy number 5–15 (within-gene range 3–15) (broad region; genes not listed).
- chr8:100,776,512–103,021,428, 61 genes, copy number 6 (broad region; genes not listed).
- chr8:104,419,512–133,814,537, 346 genes, copy number 5–28 (within-gene range 3–28) (broad region; genes not listed).
- chr9:36,833,269–41,701,096, 145 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr10:43,900,874–44,959,709, 17 genes, copy number 6–10 (within-gene range 1–10): LINC02659, LINC00841, AL139237.1, AL137026.2, AL137026.1, LINC02881, AL137026.3, CXCL12, RPL9P21, AL356157.2, AL356157.3, AL356157.1, TMEM72-AS1, EIF2AP4, AL353801.2, TMEM72, AL353801.1.
- chr10:46,286,345–48,119,455, 54 genes, copy number 8: ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R, GPRIN2, SYT15, AL356056.2, AL356056.1, SHLD2P1, LINC02637, RHEBP1, RN7SL248P, FAM245B, CTSLP3, GLUD1P2, AL731733.1, BMS1P1, RNA5SP311, AGAP13P, FRMPD2B, PTPN20, GDF10, GDF2, RBP3, ZNF488, ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, RNA5SP312, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675, SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.
- chr11:76,444,923–79,441,030, 64 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:57,415,296–58,920,504, 58 genes, copy number 5: RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3.
- chr12:61,231,159–72,186,618, 226 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr12:74,170,445–77,317,234, 57 genes, copy number 5–9: AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1, LINC02464.
- chr12:93,467,514–94,650,557, 31 genes, copy number 5 (within-gene range 1–5): MRPL42, RN7SL737P, AC025260.1, SOCS2-AS1, SOCS2, AC012085.1, CRADD, AC012085.2, RN7SL630P, AC012464.2, AC012464.1, AC012464.3, RN7SKP263, AC123567.1, PLXNC1, AC123567.2, AC073655.3, AC073655.1, AC073655.2, CEP83, RN7SL330P, RBMS2P1, CEP83-DT, AC023161.1, RN7SL483P, NSA2P2, SUCLG2P2, MIR5700, TMCC3, MIR7844, LSM3P2.
- chr15:76,586,647–101,933,350, 638 genes, copy number 5–7 (broad region; genes not listed).
- chr17:7,686,071–13,306,771, 149 genes, copy number 6–11 (broad region; genes not listed).
- chr17:15,229,773–20,681,799, 313 genes, copy number 7–22 (within-gene range 1–22) (broad region; genes not listed).
- chr17:20,938,023–28,951,771, 187 genes, copy number 5–15 (within-gene range 3–15) (broad region; genes not listed).
- chr17:29,855,759–30,186,475, 16 genes, copy number 10: RPL9P30, AC104982.2, AC104982.1, EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2, AC104984.2, NSRP1, hsa-mir-423, MIR423, MIR3184, AC104984.3, AC104984.5.
- chr17:30,477,362–30,959,322, 32 genes, copy number 5 (within-gene range 2–5): GOSR1, ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1, AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1, RN7SL316P, SUZ12P1, AC127024.7, AC127024.3, AC127024.2, AC127024.8, CRLF3, AC127024.4, AC127024.5, AC127024.6, AC127024.1, ATAD5, AC130324.2, RNU6-298P, AC130324.1, TEFM, AC130324.3, ADAP2.
- chr17:33,565,764–35,121,522, 43 genes, copy number 5–13 (within-gene range 3–13): AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3, RFFL, AC004223.3, AC004223.4, AC004223.2, AC004223.1, RAD51D, RNU6-840P, Vault.
- chr17:49,494,223–50,215,922, 37 genes, copy number 8 (within-gene range 4–8): AC015656.1, NGFR, AC006487.1, MIR6165, AC006487.2, NXPH3, SPOP, SLC35B1, AC015795.1, FAM117A, KAT7, SRP14P3, AC027801.5, TAC4, AC027801.1, AC027801.2, AC027801.4, AC027801.3, RNU6-1313P, DLX4, DLX3, AC009720.1, PICART1, ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1.
- chr17:54,477,796–60,526,242, 172 genes, copy number 5–14 (within-gene range 1–14) (broad region; genes not listed).
- chr17:61,393,456–62,841,645, 40 genes, copy number 5 (within-gene range 1–5): TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1, NACA2, BRIP1, INTS2, Y_RNA, MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A, TLK2, AC008026.1, AC008026.3, AC080038.2, AC080038.1, MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3.
- chr17:68,867,289–70,368,916, 27 genes, copy number 7: ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1.
- chr20:54,859,688–62,143,440, 134 genes, copy number 5–6 (broad region; genes not listed).
- chr22:16,405,330–17,165,445, 50 genes, copy number 6: AC137499.1, PABPC1P9, SLC9B1P4, ACTR3BP6, CHEK2P4, AP000547.2, AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3, AC007064.4, AC007064.3, ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1, AC006548.3, GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2, AC006946.3, IL17RA, AC006946.1, TMEM121B, LINC01664, HDHD5, HDHD5-AS1.
- chr22:19,121,529–23,008,356, 300 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,485. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
